Somatic mutation profile of tumor specimen C3L-06423-01 (aliquot CPT0393380006) from CPTAC case C3L-06423, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 60.2 years (21,996 days).
Specimen C3L-06423-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29053b46-ba09-4470-8ef1-013226df476a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06423-31 (Blood Derived Normal), aliquot CPT0390710002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6748b423-85dd-46bc-ba95-ae4df3823659

The open-access MAF lists 118 somatic variants for this specimen: 89 protein-altering or splice-affecting, 28 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 28, Nonsense Mutation 3, Intron 1, Frame Shift Ins 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 17/349 reads (5%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ATP9A | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 42/567 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1448351539, COSV58768944; called by muse, mutect2
- BEX4 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 23/379 reads (6%) | catalogued as rs1210792274, COSV101015316; called by muse, mutect2
- CASP1 | c.1159C>T p.P387S (on ENST00000436863 / NM_033292.4; = p.P366S on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/273 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745845552, COSV99508053; called by muse, mutect2, varscan2
- CASS4 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 34/465 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs372663259; called by muse, mutect2
- CCNT1 | c.1940A>G p.N647S | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as rs747855198; called by muse, mutect2
- CCT6B | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 32/316 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs749729604, COSV58488207; called by muse, mutect2, varscan2
- CES3 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.117); catalogued as rs200578924; called by muse, mutect2
- CHD3 | c.4453C>T p.R1485C | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs138883221; called by muse, mutect2
- CLGN | c.62T>A p.F21Y | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.177); catalogued as rs1293692826; called by muse, mutect2
- COL20A1 | c.3026C>T p.T1009M | Missense Mutation (SNP) | VAF 107/576 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs200056990, COSV100491036; called by muse, mutect2, varscan2
- COL22A1 | c.3160G>A p.G1054R | Missense Mutation (SNP) | VAF 26/269 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768586086, COSV57334923; called by muse, mutect2, varscan2
- DAB2 | c.2161C>A p.Q721K | Missense Mutation (SNP) | VAF 19/282 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.146); catalogued as COSV57920052; called by muse, mutect2
- ERG | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371043321; called by muse, mutect2
- FCRL5 | c.1157C>T p.S386F | Missense Mutation (SNP) | VAF 17/341 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1033872352, COSV62514125; called by muse, mutect2
- FGD1 | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 59/453 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs763597806; called by muse, mutect2, varscan2
- GLI3 | c.3124C>T p.R1042C | Missense Mutation (SNP) | VAF 30/543 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs944758206; called by muse, mutect2
- GPC2 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 32/556 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1454198259; called by muse, mutect2
- LRRC18 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 28/424 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138280112, COSV99630965; called by muse, mutect2
- MATK | c.337G>A p.A113T (on ENST00000310132 / NM_139355.3; = p.A114T on NM_002378.4) | Missense Mutation (SNP) | VAF 29/444 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs753406082, COSV59553894; called by muse, mutect2
- MROH2B | c.2896G>T p.E966* | Nonsense Mutation (SNP) | VAF 37/210 reads (18%) | catalogued as COSV101270917; called by muse, mutect2, varscan2
- MTHFD2L | c.466C>T p.R156* (on ENST00000395759 / NM_001144978.2; = p.R98* on NM_001004346.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 22/216 reads (10%) | catalogued as rs567368118; called by muse, mutect2
- MTRR | c.373G>T p.D125Y (on ENST00000264668; = p.D98Y on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99241807; called by muse, mutect2
- NEFH | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 48/534 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as rs753673971; called by muse, mutect2
- PADI6 | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs777296872; called by muse, mutect2
- PARD3B | c.3025C>T p.P1009S (on ENST00000406610 / NM_001302769.2; = p.P940S on NM_057177.7) | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.417); catalogued as COSV100592180; called by muse, mutect2
- PARP14 | c.5060G>A p.G1687D | Missense Mutation (SNP) | VAF 24/398 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV71734659; called by muse, mutect2
- PCDHA4 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 80/381 reads (21%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV63543526; called by muse, mutect2, varscan2
- PCDHB13 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 24/638 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.053); catalogued as COSV53394318, COSV53398477; called by muse, mutect2
- PEG10 | c.763C>T p.R255W (on ENST00000482108 / NM_001040152.2; = p.R289W on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/563 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV71788186, COSV71788360; called by muse, mutect2
- PLCXD3 | c.776G>C p.G259A | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as COSV60613948, COSV60620303; called by mutect2, varscan2
- PPFIA4 | c.2275C>T p.R759C (on ENST00000447715; = p.R760C on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 119/472 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs771493631, COSV55315131, COSV55318379; called by muse, mutect2, varscan2
- RIMBP2 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 29/419 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs774346465, COSV55480309; called by muse, mutect2
- RP2 | c.1012G>T p.D338Y | Missense Mutation (SNP) | VAF 38/303 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1805148; called by muse, mutect2, varscan2
- SH3BP5L | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 48/450 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1178079159; called by muse, mutect2, varscan2
- SLC12A3 | c.2413G>A p.A805T | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs758304056, COSV52638027; ClinVar: uncertain significance; called by muse, mutect2
- SLC30A10 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 32/678 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1040999644, COSV63072431; called by muse, mutect2
- SRP14 | c.197A>T p.K66M | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs201924463; called by muse, mutect2, varscan2
- SYNE1 | c.3933C>A p.H1311Q (on ENST00000367255 / NM_182961.4; = p.H1318Q on NM_033071.3) | Missense Mutation (SNP) | VAF 33/505 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs774093065, COSV99568074; ClinVar: uncertain significance; called by muse, mutect2
- TDRD6 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 52/728 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1408955390, COSV60177419; called by muse, mutect2
- TRIM68 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 37/471 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs147039003; called by muse, mutect2
- TRMT2B | c.1166A>G p.N389S | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774625269; called by mutect2, varscan2
- TRPS1 | c.2444C>T p.T815M (on ENST00000220888 / NM_001330599.2; = p.T828M on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/366 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); catalogued as rs1269939865, COSV55246603; called by muse, mutect2, varscan2
- WAS | c.777C>T p.D259= | Splice Region (SNP) | VAF 14/493 reads (3%) | catalogued as COSV100939511; called by muse, mutect2
- AGBL2 | c.2564G>A p.C855Y | Missense Mutation (SNP) | VAF 13/304 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.017); called by muse, mutect2
- AMTN | c.566G>C p.G189A | Missense Mutation (SNP) | VAF 26/442 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, mutect2
- APMAP | c.1038dup p.K347* | Frame Shift Ins (INS) | VAF 17/145 reads (12%) | called by mutect2, pindel, varscan2
- ARHGEF26 | c.2267A>G p.E756G | Missense Mutation (SNP) | VAF 20/378 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- BPIFB4 | c.545G>A p.G182D | Missense Mutation (SNP) | VAF 34/569 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CYP39A1 | c.1315C>T p.L439F | Missense Mutation (SNP) | VAF 18/277 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- GOLGA5 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GOLGA8H | c.1514A>T p.D505V | Missense Mutation (SNP) | VAF 22/656 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2
- GOLGA8S | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.257); called by muse, mutect2
- GSPT2 | c.1659G>C p.E553D | Missense Mutation (SNP) | VAF 36/466 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.056); called by muse, mutect2
- GTF2I | c.1163C>T p.P388L (on ENST00000573035 / NM_032999.4; = p.P347L on NM_001518.5) | Missense Mutation (SNP) | VAF 30/399 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.582); called by muse, mutect2
- HELB | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 48/292 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ING1 | c.1160A>T p.N387I | Missense Mutation (SNP) | VAF 31/448 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); called by muse, mutect2
- LAMA4 | c.1501G>A p.D501N (on ENST00000230538 / NM_001105206.3; = p.D494N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/290 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- MKRN3 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 22/674 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- MTCL1 | c.856C>G p.P286A | Missense Mutation (SNP) | VAF 26/629 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.211); called by muse, mutect2
- MUC16 | c.14989A>T p.T4997S | Missense Mutation (SNP) | VAF 32/436 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.149); called by muse, mutect2
- NAALADL1 | c.1201A>T p.T401S | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NCOA6 | c.2626G>C p.V876L | Missense Mutation (SNP) | VAF 28/378 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2
- OR6J1 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 19/309 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- OTUD1 | c.875T>G p.L292R | Missense Mutation (SNP) | VAF 43/534 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.069); called by muse, mutect2
- PCDHA9 | c.1513T>C p.S505P | Missense Mutation (SNP) | VAF 31/306 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PIEZO2 | c.7465T>C p.Y2489H | Missense Mutation (SNP) | VAF 23/300 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PIK3R1 | c.1213A>C p.I405L (on ENST00000521381 / NM_181523.3; = p.I135L on NM_181504.4) | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2
- POFUT1 | c.979-1G>A p.X327_splice | Splice Site (SNP) | VAF 17/289 reads (6%) | called by muse, mutect2
- PTPRM | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT tolerated (0.87); PolyPhen benign (0.04); called by muse, mutect2
- RAB39B | c.624G>T p.E208D | Missense Mutation (SNP) | VAF 24/279 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- RBM25 | c.513A>T p.E171D | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.935); called by muse, mutect2
- RESF1 | c.3368A>G p.D1123G | Missense Mutation (SNP) | VAF 9/263 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.342); called by muse, mutect2
- SIX5 | c.1555A>G p.I519V | Missense Mutation (SNP) | VAF 38/462 reads (8%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.48); called by muse, mutect2
- SLIT2 | c.1505C>G p.A502G | Missense Mutation (SNP) | VAF 28/259 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- STAP1 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 17/239 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- SUGCT | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- THBS1 | c.525G>T p.E175D | Missense Mutation (SNP) | VAF 27/372 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2
- TOGARAM1 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2
- TPT1 | c.132T>G p.D44E | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2
- TRMT9B | c.472G>C p.V158L | Missense Mutation (SNP) | VAF 43/292 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- TTN | c.73078G>A p.A24360T (on ENST00000591111; = p.A16936T on NM_003319.4) | Missense Mutation (SNP) | VAF 32/375 reads (9%) | PolyPhen benign (0.003); called by muse, mutect2
- TTN | c.63796G>C p.V21266L (on ENST00000591111; = p.V13842L on NM_003319.4) | Missense Mutation (SNP) | VAF 27/352 reads (8%) | PolyPhen benign (0.005); called by muse, mutect2
- UCKL1 | c.1531C>T p.R511W | Missense Mutation (SNP) | VAF 22/470 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); called by muse, mutect2
- UGT1A1 | c.1174C>A p.P392T | Missense Mutation (SNP) | VAF 25/402 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WNK3 | c.2294C>T p.T765I | Missense Mutation (SNP) | VAF 14/315 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF461 | c.1596T>A p.N532K | Missense Mutation (SNP) | VAF 22/305 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- ZNF536 | c.3200A>C p.N1067T | Missense Mutation (SNP) | VAF 23/478 reads (5%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2
- ZNF653 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 22/409 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCA9 | c.4083G>A p.L1361= | Silent (SNP) | VAF 44/339 reads (13%) | called by muse, mutect2, varscan2
- CACNA1H | c.3552C>T p.A1184= | Silent (SNP) | VAF 74/575 reads (13%) | catalogued as rs1252142664; called by muse, mutect2, varscan2
- CARMIL2 | c.1431C>T p.D477= | Silent (SNP) | VAF 26/370 reads (7%) | catalogued as rs1240662885; called by muse, mutect2
- CHRNA3 | c.501G>A p.P167= | Silent (SNP) | VAF 22/388 reads (6%) | catalogued as rs577413653, COSV58775177; called by muse, mutect2
- DNAH10 | c.2412G>A p.S804= (on ENST00000409039; = p.S743= on NM_207437.3) | Silent (SNP) | VAF 24/270 reads (9%) | catalogued as rs371716816; called by muse, mutect2
- DNAH5 | c.4737G>A p.S1579= | Silent (SNP) | VAF 45/297 reads (15%) | catalogued as rs938971019; called by muse, mutect2, varscan2
- EIF2A | c.918T>C p.C306= | Silent (SNP) | VAF 23/340 reads (7%) | called by muse, mutect2
- ELOA2 | c.687G>A p.S229= | Silent (SNP) | VAF 18/446 reads (4%) | called by muse, mutect2
- FASN | c.3813G>A p.T1271= | Silent (SNP) | VAF 109/540 reads (20%) | catalogued as rs756562385; called by muse, mutect2, varscan2
- HAS1 | c.1278C>T p.G426= | Silent (SNP) | VAF 29/582 reads (5%) | catalogued as rs768986847, COSV55789259; called by muse, mutect2
- KCNH1 | c.768C>T p.I256= | Silent (SNP) | VAF 27/467 reads (6%) | catalogued as rs764963478; called by muse, mutect2
- MAGIX | c.126G>A p.A42= | Silent (SNP) | VAF 45/593 reads (8%) | called by muse, mutect2
- MMRN1 | c.2935C>T p.L979= | Silent (SNP) | VAF 16/368 reads (4%) | called by muse, mutect2
- NOX3 | c.606G>A p.L202= | Silent (SNP) | VAF 43/397 reads (11%) | called by muse, mutect2, varscan2
- NRG3 | c.72C>T p.G24= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as COSV64548087; called by muse, mutect2
- NT5DC3 | c.336G>A p.K112= | Silent (SNP) | VAF 29/336 reads (9%) | called by muse, mutect2
- OGT | c.1257G>A p.T419= | Silent (SNP) | VAF 102/388 reads (26%) | catalogued as rs1182662606, COSV101035534; called by muse, mutect2, varscan2
- PARD6G | c.7C>A p.R3= | Silent (SNP) | VAF 18/362 reads (5%) | called by muse, mutect2
- PES1 | c.468G>A p.Q156= | Silent (SNP) | VAF 29/440 reads (7%) | called by muse, mutect2
- POU3F1 | c.534G>A p.A178= | Silent (SNP) | VAF 13/314 reads (4%) | called by muse, mutect2
- PRR33 | c.18G>A p.A6= | Silent (SNP) | VAF 10/273 reads (4%) | catalogued as rs1448888320; called by muse, mutect2
- RBM10 | c.2694C>A p.G898= | Silent (SNP) | VAF 63/376 reads (17%) | called by muse, mutect2, varscan2
- RNF32 | c.435C>T p.S145= | Silent (SNP) | VAF 14/370 reads (4%) | called by muse, mutect2
- SPART | c.1350G>A p.Q450= | Silent (SNP) | VAF 26/357 reads (7%) | catalogued as COSV100768744; called by muse, mutect2
- TAF1 | c.18C>T p.S6= | Silent (SNP) | VAF 63/535 reads (12%) | catalogued as rs771117995; called by muse, mutect2, varscan2
- TMEM200C | c.1344G>A p.A448= | Silent (SNP) | VAF 18/421 reads (4%) | catalogued as rs1567886961; called by muse, mutect2
- TNNI1 | c.366C>T p.A122= | Silent (SNP) | VAF 43/427 reads (10%) | called by muse, mutect2, varscan2
- WWP1 | c.153G>A p.T51= | Silent (SNP) | VAF 26/258 reads (10%) | catalogued as rs573309707, COSV55357916; called by muse, mutect2, varscan2
- PGC | c.648-479C>G | Intron (SNP) | VAF 902/1285 reads (70%) | called by muse, mutect2, varscan2
